Gene-level copy-number profile of tumor specimen TCGA-FT-A61P-01A from TCGA case TCGA-FT-A61P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.9 years (28,082 days).
Specimen TCGA-FT-A61P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.8dbfe639-c943-45b3-b71e-c491b070e1a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FT-A61P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d6250df-966a-43a6-900a-35bf423c4613

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 2,267; copy number 3: 21,248; copy number 4: 15,269; copy number 5: 8,909; copy number 6: 9,806; copy number 7: 862; copy number 8: 1,201; copy number 11: 48; copy number 12: 63; copy number 16: 4; copy number 23: 6; copy number 27: 1; copy number 33: 2; copy number 35: 1; copy number 36: 9; copy number 41: 6; copy number 42: 11; copy number 47: 16; copy number 65: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FT-A61P-01A-11D-A30D-01): tumor purity 0.31, ploidy 3.83, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,319 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–154,979,251, 517 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–32,888,145, 497 genes, copy number 7–8 (broad region; genes not listed).
- chr5:32,947,443–33,026,025, 3 genes, copy number 7: LINC02120, AC034223.1, AC034223.2.
- chr5:35,429,064–37,249,421, 34 genes, copy number 7 (within-gene range 4–7): U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17.
- chr8:36,887,456–40,897,833, 92 genes, copy number 12–47 (broad region; genes not listed).
- chr8:41,426,655–43,077,334, 48 genes, copy number 11 (within-gene range 4–11): SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1.
- chr10:9,275,833–14,462,142, 80 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr11:54,591,480–56,165,921, 77 genes, copy number 42–65 (broad region; genes not listed).
- chr12:67,065,018–68,971,570, 49 genes, copy number 7–65: AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr13:18,467,172–33,350,630, 337 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr13:66,268,997–114,337,626, 585 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
